Somatic mutation profile of tumor specimen TARGET-40-NAAGKM-01A (aliquot TARGET-40-NAAGKM-01A-01D) from TARGET case TARGET-40-NAAGKM, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 13.1 years (4,788 days).
Specimen TARGET-40-NAAGKM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee30699f-a02e-470b-8801-1503a6b3e59c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAGKM-10B (Blood Derived Normal), aliquot TARGET-40-NAAGKM-10B-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f950f59a-9137-4bb2-9841-b4630fdf5dfe

The open-access MAF lists 29 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 5, Nonsense Mutation 2, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 113/137 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587781504, COSV52708806, COSV52766179, COSV52793434; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- B3GNT3 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.027); catalogued as COSV100592759; called by muse, mutect2, varscan2
- DCLRE1A | c.1652C>T p.T551I | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.174); catalogued as rs768440076; called by muse, mutect2
- ISM2 | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs761557845, COSV53634328; called by muse, mutect2, varscan2
- KCTD8 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as rs141663296; called by muse, mutect2, varscan2
- RB1CC1 | c.754G>T p.E252* | Nonsense Mutation (SNP) | VAF 88/279 reads (32%) | catalogued as COSV50242990, COSV50243469; called by muse, mutect2, varscan2
- TMC5 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 127/218 reads (58%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.617); catalogued as COSV66867829; called by muse, mutect2, varscan2
- VWDE | c.778C>T p.L260F | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1199170806; called by muse, mutect2, varscan2
- GHITM | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- HCN1 | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KLHL1 | c.554C>A p.S185Y | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); called by muse, mutect2
- MAGEB3 | c.512T>G p.V171G | Missense Mutation (SNP) | VAF 58/79 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- MC5R | c.260T>A p.M87K | Missense Mutation (SNP) | VAF 92/341 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- MED13 | c.1442C>A p.S481Y | Missense Mutation (SNP) | VAF 79/165 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- MMRN1 | c.2634T>G p.I878M | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PPBP | c.365C>A p.A122E | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RABEP1 | c.557C>A p.S186Y | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- RB1CC1 | c.755A>T p.E252V | Missense Mutation (SNP) | VAF 87/276 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHANK2 | c.1936G>A p.A646T | Missense Mutation (SNP) | VAF 64/190 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- SLC52A1 | c.134G>A p.W45* | Nonsense Mutation (SNP) | VAF 34/89 reads (38%) | called by muse, mutect2, varscan2
- TACR2 | c.409C>T p.H137Y | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- WASHC2C | c.4000C>A p.P1334T (on ENST00000336378; = p.P1313T on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 223/337 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV1-9 | c.39G>C p.L13= | Silent (SNP) | VAF 126/340 reads (37%) | called by muse, mutect2, varscan2
- ITGAV | c.2637G>A p.G879= | Silent (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2, varscan2
- KIF13A | c.595T>C p.L199= | Silent (SNP) | VAF 28/52 reads (54%) | called by muse, mutect2, varscan2
- POLR1F | c.522T>C p.G174= | Silent (SNP) | VAF 15/183 reads (8%) | called by muse, mutect2
- SLC18A1 | c.444G>A p.V148= | Silent (SNP) | VAF 53/93 reads (57%) | catalogued as COSV52351536; called by muse, mutect2, varscan2
- CSGALNACT1 | c.-234G>C | 5'UTR (SNP) | VAF 70/112 reads (63%) | catalogued as rs1361445978; called by muse, mutect2, varscan2
- ZNF658B | n.2497A>G | RNA (SNP) | VAF 98/479 reads (20%) | called by muse, mutect2, varscan2
